Gene-level copy-number profile of tumor specimen TCGA-CN-5360-01A from TCGA case TCGA-CN-5360, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 68.5 years (25,034 days).
Specimen TCGA-CN-5360-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.7826cab7-cb8e-47ce-af9f-52a8c7d54966.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-5360-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e7b465c4-dcc8-41cf-ac4f-06e065251e80

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 24,555; copy number 2: 30,337; copy number 3: 1,761; copy number 4: 2,971; copy number 5: 171; copy number 16: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-5360-01A-01D-1432-01): tumor purity 0.53, ploidy 1.72, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 179 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:46,993,723–58,118,070, 179 genes, copy number 5–16 (within-gene range 1–16) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 22,141. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
